Surgical pathology report (de-identified scan), TCGA case TCGA-26-5139, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5139-01A (Primary Tumor).

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

- A. Left brain mass () A. Frozen Section Charge ()
B. Left brain mass ()

CLINICAL HISTORY: and
CT revealed a 5.2 x 4.5 x 3.5 cm mass in the left
(illegible) region.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Left brain mass
B. Left brain mass
A. The specimen is received fresh for frozen section and consists of a two ovoid pieces of pink-tan soft tissue, each of which is 0.3 cm in greatest dimension. A touch prep is made and a representative portion of the specimen is submitted for frozen section. The frozen section diagnosis is "Malignant glioma" by . The frozen section tissue is submitted entirely for permanent processing in cassette FSA1, and the remainder is submitted in cassette A2.
B. The specimen is received fresh and consists of multiple pieces of tan soft tissue ranging from 0.2 up to 1.2 cm in greatest dimension. The largest piece is trisected and the specimen is entirely submitted in cassette B1.

(DIAGNOSIS:

- A. "Left brain mass":
Glioblastoma multiforme (WHO Grade IV)
B. "Left brain mass":
Glioblastoma multiforme (WHO Grade IV)

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist:

Note: Test systems have been developed and their performance characteristics determined by s. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of as qualified to perform high complexity clinical laboratory testing.

Pathologist

Electronically signed

Source: NCI Genomic Data Commons file f605f124-72c6-4de5-bb06-45332dc2c850 (TCGA-26-5139.CAF0E16D-4F03-48E2-B5DF-04C0E5720B22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).